Somatic mutation profile of tumor specimen TCGA-B5-A0JS-01A (aliquot TCGA-B5-A0JS-01A-11D-A10B-09) from TCGA case TCGA-B5-A0JS, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G1; Age at diagnosis: 54.7 years (19,995 days).
Specimen TCGA-B5-A0JS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7aa1b262-170b-44c6-a972-e09107c2377d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B5-A0JS-10A (Blood Derived Normal), aliquot TCGA-B5-A0JS-10A-01D-A10O-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/12aee5de-61a5-44b5-b39c-1881f47e1516

The open-access MAF lists 34 somatic variants for this specimen: 28 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 5, Nonsense Mutation 3, Frame Shift Del 1, Frame Shift Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1A | c.5164C>T p.R1722* | Nonsense Mutation (SNP) | VAF 44/107 reads (41%) | hotspot (GDC flag); catalogued as rs1485978447, COSV61371609; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 96/133 reads (72%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 32/91 reads (35%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.380G>T p.G127V | Missense Mutation (SNP) | VAF 74/188 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs398123322, COSV64289089, COSV64294277; ClinVar: uncertain significance; called by muse, varscan2
- PTEN | c.419T>G p.L140* | Nonsense Mutation (SNP) | VAF 58/146 reads (40%) | hotspot (GDC flag); catalogued as COSV64289095, COSV64298590; called by muse, varscan2
- ADCY8 | c.1246C>G p.L416V | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53895961, COSV99654440; called by muse, mutect2, varscan2
- AKAP6 | c.4958G>T p.S1653I | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55204638; called by muse, mutect2, varscan2
- BNC1 | c.1135G>A p.V379I | Missense Mutation (SNP) | VAF 71/185 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1415662180, COSV61756473; called by muse, mutect2, varscan2
- CYP2J2 | c.238A>G p.S80G | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.25); catalogued as rs753240136, COSV64605408; called by muse, mutect2, varscan2
- DSCAM | c.1136A>G p.D379G | Missense Mutation (SNP) | VAF 59/166 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as COSV68020575; called by muse, mutect2, varscan2
- GDA | c.514G>T p.D172Y | Missense Mutation (SNP) | VAF 88/246 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52990247; called by muse, mutect2, varscan2
- GID8 | c.683A>G p.K228R | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.095); catalogued as COSV56610899; called by muse, mutect2, varscan2
- GRAMD2B | c.1106A>G p.N369S | Missense Mutation (SNP) | VAF 41/118 reads (35%) | SIFT tolerated (0.57); PolyPhen benign (0.01); catalogued as COSV53505770; called by muse, mutect2, varscan2
- GUCY2D | c.2812C>T p.P938S | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV54694395; called by muse, mutect2, varscan2
- INPP4B | c.889C>T p.R297* | Nonsense Mutation (SNP) | VAF 17/162 reads (10%) | catalogued as rs748052310, COSV53710700; called by muse, mutect2, varscan2
- JADE2 | c.475A>G p.R159G | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as COSV50911579; called by muse, mutect2, varscan2
- KANSL1 | c.1040C>T p.T347I | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52264925; called by muse, mutect2, varscan2
- KAT7 | c.1585C>T p.R529C | Missense Mutation (SNP) | VAF 52/163 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs767303949, COSV52013022; called by muse, mutect2, varscan2
- KDM3B | c.1804del p.T602Lfs*9 | Frame Shift Del (DEL) | VAF 14/40 reads (35%) | catalogued as COSV58687874; called by mutect2, pindel, varscan2
- MEAF6 | c.239G>T p.R80L | Missense Mutation (SNP) | VAF 11/183 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as COSV56162605, COSV56163847; called by muse, mutect2
- PCDHB6 | c.1183G>A p.V395M | Missense Mutation (SNP) | VAF 45/133 reads (34%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.011); catalogued as rs750545117, COSV50689702; called by muse, mutect2, varscan2
- PEG3 | c.1780C>T p.R594C | Missense Mutation (SNP) | VAF 55/142 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs764907402, COSV55624386; called by muse, mutect2, varscan2
- RNF213 | c.2612C>T p.S871F | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as COSV60618795; called by muse, mutect2, varscan2
- SLC36A3 | c.943G>A p.A315T | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as rs1050822768, COSV58855484; called by muse, mutect2, varscan2
- USH2A | c.6775G>A p.V2259I | Missense Mutation (SNP) | VAF 55/159 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56326286; called by muse, mutect2, varscan2
- WDR83OS | c.34C>T p.P12S | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as COSV54417268; called by muse, mutect2, varscan2
- PHC2 | c.1085C>T p.P362L | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2
- ZMYM2 | c.1292dup p.T432Nfs*2 | Frame Shift Ins (INS) | VAF 40/133 reads (30%) | called by mutect2, pindel, varscan2
- AADAC | c.1089G>A p.V363= | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as COSV51758167; called by muse, mutect2, varscan2
- APBA2 | c.93C>T p.S31= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as rs557200678, COSV68788505; called by muse, mutect2, varscan2
- CELA2A | c.210G>A p.T70= | Silent (SNP) | VAF 7/66 reads (11%) | catalogued as rs377663645; called by muse, mutect2, varscan2
- DVL1 | c.1062G>A p.P354= | Silent (SNP) | VAF 6/13 reads (46%) | catalogued as rs1160297819, COSV59562139; called by muse, mutect2, varscan2
- IRF2 | c.639G>A p.P213= | Silent (SNP) | VAF 17/66 reads (26%) | catalogued as rs758246792, COSV101165803, COSV66928411; called by muse, mutect2, varscan2
- MIR106A | n.9A>C | RNA (SNP) | VAF 25/73 reads (34%) | called by muse, mutect2, varscan2
